CCDI case PBBVTU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b1e3354a-9b5a-43e9-9398-8c716160ca3c

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Rhabdoid tumor, NOS: ICD-O-3 morphology code: 8963/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 0.4 years (142 days).

Biospecimens (3 samples)
- Sample 0DIKJJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIKJR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIKK6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
